Gene-level copy-number profile of tumor specimen TCGA-A6-5657-01A from TCGA case TCGA-A6-5657, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 65.5 years (23,920 days).
Specimen TCGA-A6-5657-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.c1627bec-7f00-4dd2-b430-123390367177.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A6-5657-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d66cc27c-1a64-4a06-b3c6-37d2b9662dc2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,369; copy number 2: 45,013; copy number 3: 9,697; copy number 5: 1,311; copy number 6: 427.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A6-5657-01A-01D-1649-01): tumor purity 0.32, ploidy 2.13, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,738 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:41,653,220–41,896,762, 1 gene, copy number 6 (within-gene range 1–11): ANK1.
- chr8:41,803,349–145,066,685, 1,594 genes, copy number 5–6 (broad region; genes not listed).
- chr22:29,259,872–32,285,131, 143 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,369. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
